Somatic mutation profile of tumor specimen TCGA-DU-7010-01A (aliquot TCGA-DU-7010-01A-11D-2024-08) from TCGA case TCGA-DU-7010, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Astrocytoma, anaplastic; Tissue or organ of origin: Cerebrum; Tumor grade: G3; Age at diagnosis: 58.0 years (21,199 days).
Specimen TCGA-DU-7010-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ba9a0cdc-9e44-466b-ab8e-5a66ad084289.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DU-7010-10A (Blood Derived Normal), aliquot TCGA-DU-7010-10A-01D-2024-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/68762a23-a68e-4c66-9e58-301a0cb19b7a

The open-access MAF lists 103 somatic variants for this specimen: 79 protein-altering or splice-affecting, 19 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 70, Silent 19, Frame Shift Del 5, Nonsense Mutation 2, 3'Flank 2, 5'UTR 1, 5'Flank 1, Splice Region 1, 3'UTR 1, Nonstop Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 22/70 reads (31%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- TP53 | c.536A>G p.H179R | Missense Mutation (SNP) | VAF 37/46 reads (80%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs1057519991, COSV52661025, COSV52661712, COSV52690692, COSV52937418; ClinVar: uncertain significance / pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCA7 | c.303G>A p.L101= | Splice Region (SNP) | VAF 4/15 reads (27%) | catalogued as COSV54035678; called by muse, mutect2
- ACOT11 | c.1465G>A p.V489M | Missense Mutation (SNP) | VAF 11/80 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs771940818, COSV56362911; called by muse, mutect2, varscan2
- ACOT4 | c.505G>A p.G169S | Missense Mutation (SNP) | VAF 22/84 reads (26%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.537); catalogued as COSV58336183; called by muse, varscan2
- ADAM2 | c.10G>A p.V4I | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT tolerated (0.3); PolyPhen benign (0.007); catalogued as rs769082387, COSV55864232; called by muse, mutect2, varscan2
- ADGRG4 | c.5115G>C p.Q1705H | Missense Mutation (SNP) | VAF 27/198 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.984); catalogued as COSV54964316; called by muse, mutect2, varscan2
- AKAP4 | c.1283A>G p.K428R | Missense Mutation (SNP) | VAF 41/145 reads (28%) | SIFT tolerated (0.45); PolyPhen benign (0.013); catalogued as rs1557203962, COSV62075280; called by muse, mutect2, varscan2
- ANKRD26 | c.3703del p.Q1235Nfs*18 | Frame Shift Del (DEL) | VAF 10/84 reads (12%) | catalogued as rs1345723762; called by mutect2, pindel, varscan2
- APC | c.5423A>C p.N1808T | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.011); catalogued as COSV57371481; called by muse, mutect2, varscan2
- CACNA1E | c.1208G>A p.G403E | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT tolerated (0.95); PolyPhen benign (0.109); catalogued as COSV100701474, COSV62412818; called by muse, mutect2, varscan2
- CCT7 | c.80G>A p.S27N | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV57823395; called by muse, mutect2, varscan2
- CDH12 | c.893T>G p.F298C | Missense Mutation (SNP) | VAF 23/111 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.361); catalogued as COSV66438520; called by muse, mutect2, varscan2
- CLPTM1L | c.1072G>A p.A358T | Missense Mutation (SNP) | VAF 13/103 reads (13%) | SIFT tolerated (0.18); PolyPhen benign (0.052); catalogued as rs759753432, COSV57992321; called by muse, mutect2, varscan2
- CNKSR2 | c.2423C>A p.S808Y | Missense Mutation (SNP) | VAF 28/97 reads (29%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.825); catalogued as COSV54263951; called by muse, mutect2, varscan2
- CSH1 | c.610C>T p.R204C | Missense Mutation (SNP) | VAF 19/142 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.936); catalogued as rs139446025; called by muse, mutect2, varscan2
- CYTH3 | c.304G>A p.A102T | Missense Mutation (SNP) | VAF 17/92 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.629); catalogued as COSV100641711, COSV63440643; called by muse, mutect2, varscan2
- CYTH4 | c.461C>T p.P154L | Missense Mutation (SNP) | VAF 3/23 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1228760288, COSV50635143; called by muse, mutect2
- DISP2 | c.397C>A p.R133S | Missense Mutation (SNP) | VAF 6/55 reads (11%) | SIFT tolerated (0.46); PolyPhen benign (0.005); catalogued as COSV51136743; called by muse, mutect2, varscan2
- DMBT1 | c.2953G>A p.V985I (on ENST00000338354 / NM_001377530.1; = p.V486I on NM_004406.3) | Missense Mutation (SNP) | VAF 20/85 reads (24%) | SIFT tolerated (0.65); PolyPhen possibly damaging (0.475); catalogued as COSV57556939; called by muse, mutect2, varscan2
- EDAR | c.92G>A p.C31Y | Missense Mutation (SNP) | VAF 5/42 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV51506741; called by muse, mutect2, varscan2
- FAM47B | c.922C>T p.R308C | Missense Mutation (SNP) | VAF 30/107 reads (28%) | SIFT tolerated (0.32); PolyPhen benign (0.003); catalogued as rs779361808, COSV61452630; called by muse, mutect2, varscan2
- FBN2 | c.1154A>C p.K385T | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.639); catalogued as COSV52538107; called by muse, mutect2, varscan2
- FLG | c.2908C>A p.H970N | Missense Mutation (SNP) | VAF 66/537 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.088); catalogued as COSV64246823; called by muse, mutect2, varscan2
- GAK | c.2442G>C p.E814D | Missense Mutation (SNP) | VAF 19/113 reads (17%) | SIFT tolerated (0.21); PolyPhen benign (0.101); catalogued as rs1043369485, COSV58508439; called by muse, mutect2, varscan2
- GALNT1 | c.343C>T p.L115F | Missense Mutation (SNP) | VAF 16/136 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.916); catalogued as COSV52454461; called by muse, mutect2, varscan2
- GPAM | c.1850G>A p.R617Q | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT tolerated (0.24); PolyPhen benign (0.172); catalogued as rs556698222, COSV62082258; called by muse, mutect2, varscan2
- GSDMD | c.4G>T p.G2W | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.715); catalogued as COSV52798065; called by muse, mutect2, varscan2
- HRH4 | c.371C>G p.T124S | Missense Mutation (SNP) | VAF 12/114 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.029); catalogued as COSV56929414; called by muse, mutect2, varscan2
- HSF5 | c.1426C>G p.Q476E | Missense Mutation (SNP) | VAF 90/174 reads (52%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.854); catalogued as COSV60418897; called by muse, mutect2
- IFNA5 | c.299G>T p.W100L | Missense Mutation (SNP) | VAF 39/265 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.721); catalogued as COSV52387420; called by muse, mutect2, varscan2
- IKBKE | c.401G>A p.R134H | Missense Mutation (SNP) | VAF 6/84 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1464747771, COSV65625883; called by muse, mutect2
- INTS6L | c.1652T>A p.V551D | Missense Mutation (SNP) | VAF 25/131 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as COSV66085723; called by muse, mutect2, varscan2
- ITPRIPL2 | c.598G>T p.A200S | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT tolerated (0.51); PolyPhen benign (0.1); catalogued as COSV67348018; called by muse, mutect2, varscan2
- JMJD6 | c.1033G>A p.D345N | Missense Mutation (SNP) | VAF 10/87 reads (11%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.985); catalogued as COSV58302489; called by muse, mutect2, varscan2
- KIAA1522 | c.1756C>T p.R586C (on ENST00000373480 / NM_001198972.2; = p.R645C on NM_020888.3) | Missense Mutation (SNP) | VAF 17/180 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.858); catalogued as rs200907113, COSV53867087; called by muse, mutect2, varscan2
- LONRF3 | c.2006del p.G669Dfs*21 (on ENST00000371628 / NM_001031855.3; = p.G628Dfs*21 on NM_024778.5) | Frame Shift Del (DEL) | VAF 49/284 reads (17%) | catalogued as COSV100504356; called by mutect2, pindel, varscan2
- MACF1 | c.10945C>T p.L3649F (on ENST00000372915; = p.L1582F on NM_012090.5) | Missense Mutation (SNP) | VAF 15/132 reads (11%) | catalogued as COSV57138128; called by muse, mutect2, varscan2
- MAGEA3 | c.446T>C p.V149A | Missense Mutation (SNP) | VAF 86/194 reads (44%) | SIFT tolerated (0.44); PolyPhen benign (0.204); catalogued as rs1556826393, COSV64756437; called by muse, mutect2, varscan2
- MAGEC2 | c.1122A>T p.*374Cext*4 | Nonstop Mutation (SNP) | VAF 22/99 reads (22%) | catalogued as COSV56001004; called by muse, mutect2, varscan2
- MAPKAPK5 | c.748A>G p.I250V | Missense Mutation (SNP) | VAF 27/161 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.31); catalogued as COSV72431659; called by muse, mutect2, varscan2
- MED12 | c.2474C>A p.T825N | Missense Mutation (SNP) | VAF 20/118 reads (17%) | SIFT tolerated (0.56); PolyPhen probably damaging (0.926); catalogued as COSV61352158; called by muse, mutect2, varscan2
- MFSD6L | c.1001C>A p.A334D | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as COSV61003090, COSV61005100; called by muse, mutect2, varscan2
- MTMR7 | c.445A>T p.S149C | Missense Mutation (SNP) | VAF 31/83 reads (37%) | SIFT tolerated (0.09); PolyPhen benign (0.1); catalogued as COSV51669594; called by muse, mutect2, varscan2
- NFATC4 | c.860G>A p.R287H | Missense Mutation (SNP) | VAF 19/39 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51608664; called by muse, mutect2, varscan2
- NKAP | c.512G>T p.S171I | Missense Mutation (SNP) | VAF 17/69 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.88); catalogued as COSV65056837; called by muse, mutect2, varscan2
- NPAP1 | c.3456T>A p.C1152* | Nonsense Mutation (SNP) | VAF 17/96 reads (18%) | catalogued as COSV61510308; called by muse, mutect2, varscan2
- NUP188 | c.1805C>T p.T602I | Missense Mutation (SNP) | VAF 20/166 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.326); catalogued as COSV65364240; called by muse, mutect2, varscan2
- OR2T4 | c.143G>T p.G48V | Missense Mutation (SNP) | VAF 26/191 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV63544899; called by muse, mutect2, varscan2
- OR5M3 | c.473C>A p.T158K | Missense Mutation (SNP) | VAF 28/125 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56568132; called by muse, mutect2, varscan2
- OR7G3 | c.404T>A p.I135N | Missense Mutation (SNP) | VAF 19/100 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); catalogued as COSV59640868; called by muse, mutect2, varscan2
- PDK3 | c.752A>T p.N251I | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV64794199; called by muse, mutect2
- PLA2G4A | c.1616A>G p.D539G | Missense Mutation (SNP) | VAF 14/90 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.927); catalogued as COSV66556056; called by muse, mutect2, varscan2
- POLR3GL | c.546G>C p.E182D | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT tolerated (0.28); PolyPhen benign (0.001); catalogued as COSV65215315, COSV65216010; called by muse, mutect2, varscan2
- PPP2R2C | c.1100G>A p.R367Q | Missense Mutation (SNP) | VAF 6/51 reads (12%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.894); catalogued as rs367696094; called by muse, mutect2
- PRAMEF2 | c.38C>A p.A13E | Missense Mutation (SNP) | VAF 30/202 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV53578275; called by muse, mutect2, varscan2
- PRPF31 | c.865C>T p.R289W | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as rs780317796, COSV58086665; called by muse, mutect2, varscan2
- PTPRH | c.1553C>T p.T518I | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT tolerated (0.25); PolyPhen benign (0.012); catalogued as rs777927375, COSV54748845; called by muse, mutect2, varscan2
- RIOK3 | c.783G>T p.K261N | Missense Mutation (SNP) | VAF 9/91 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1366551175, COSV59774633; called by muse, mutect2, varscan2
- SACM1L | c.71A>G p.D24G | Missense Mutation (SNP) | VAF 20/80 reads (25%) | SIFT tolerated (0.16); PolyPhen benign (0.007); catalogued as rs745558204, COSV66614652; called by muse, mutect2, varscan2
- SDR42E1 | c.62G>C p.G21A | Missense Mutation (SNP) | VAF 14/73 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV61094944; called by muse, mutect2, varscan2
- SPTBN4 | c.5872A>G p.M1958V | Missense Mutation (SNP) | VAF 14/96 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV58956949; called by muse, mutect2, varscan2
- SULT2B1 | c.477C>A p.Y159* (on ENST00000201586 / NM_177973.2; = p.Y144* on NM_004605.2) | Nonsense Mutation (SNP) | VAF 3/28 reads (11%) | catalogued as COSV52378113; called by muse, mutect2
- SULT2B1 | c.478T>A p.S160T (on ENST00000201586 / NM_177973.2; = p.S145T on NM_004605.2) | Missense Mutation (SNP) | VAF 3/27 reads (11%) | SIFT tolerated (0.39); PolyPhen benign (0.082); catalogued as COSV52378123; called by muse, mutect2
- TAF1L | c.1184T>C p.V395A | Missense Mutation (SNP) | VAF 43/271 reads (16%) | SIFT tolerated (0.76); PolyPhen benign (0); catalogued as COSV54267145; called by muse, varscan2
- TBCK | c.2640A>G p.I880M (on ENST00000273980 / NM_001163436.4; = p.I817M on NM_033115.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT tolerated (0.14); PolyPhen benign (0.071); catalogued as COSV56761318; called by muse, mutect2, varscan2
- TCHHL1 | c.135del p.Q46Sfs*15 | Frame Shift Del (DEL) | VAF 91/330 reads (28%) | catalogued as rs749179121; called by mutect2, pindel, varscan2
- TLR10 | c.622C>T p.R208C | Missense Mutation (SNP) | VAF 8/92 reads (9%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as rs376747590; called by muse, mutect2
- TRIM13 | c.253A>G p.I85V | Missense Mutation (SNP) | VAF 55/83 reads (66%) | SIFT deleterious (0.02); PolyPhen benign (0.341); catalogued as COSV53951185; called by muse, mutect2, varscan2
- TTC26 | c.1214C>G p.A405G | Missense Mutation (SNP) | VAF 9/73 reads (12%) | SIFT tolerated (0.11); PolyPhen benign (0.034); catalogued as COSV58273833; called by muse, mutect2, varscan2
- USP20 | c.1339G>T p.D447Y | Missense Mutation (SNP) | VAF 48/193 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59617813; called by muse, mutect2, varscan2
- WFIKKN2 | c.713G>A p.R238Q | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT tolerated (0.3); PolyPhen benign (0.243); catalogued as rs370465261, COSV60959897; called by muse, mutect2, varscan2
- XK | c.320G>A p.R107K | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT tolerated (0.78); PolyPhen benign (0.026); catalogued as COSV66120719; called by muse, mutect2, varscan2
- ZBTB21 | c.2689C>T p.P897S | Missense Mutation (SNP) | VAF 5/84 reads (6%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as COSV60405378; called by muse, mutect2
- ZNF30 | c.923G>T p.R308I | Missense Mutation (SNP) | VAF 37/102 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.529); catalogued as rs201795798, COSV57853961, COSV57855535; called by muse, mutect2, varscan2
- ATRX | c.4238_4268del p.E1413Gfs*67 | Frame Shift Del (DEL) | VAF 41/115 reads (36%) | called by mutect2, pindel
- FFAR2 | c.364C>T p.R122W | Missense Mutation (SNP) | VAF 4/72 reads (6%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); called by muse, mutect2
- PRAMEF17 | c.1407C>A p.D469E | Missense Mutation (SNP) | VAF 23/229 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- RBBP6 | c.3311del p.P1104Qfs*7 | Frame Shift Del (DEL) | VAF 16/48 reads (33%) | called by mutect2, pindel, varscan2
- AC100868.1 | c.1596G>A p.P532= | Silent (SNP) | VAF 12/61 reads (20%) | catalogued as rs772606504, COSV51840052; called by muse, mutect2, varscan2
- BCL2L13 | c.468T>G p.P156= | Silent (SNP) | VAF 12/109 reads (11%) | catalogued as COSV58227154; called by muse, mutect2, varscan2
- BLZF1 | c.483A>G p.L161= | Silent (SNP) | VAF 63/189 reads (33%) | catalogued as COSV61394597; called by muse, mutect2, varscan2
- BRPF1 | c.1200C>T p.C400= | Silent (SNP) | VAF 20/79 reads (25%) | catalogued as COSV57407102; called by muse, mutect2, varscan2
- CDH24 | c.588G>A p.L196= | Silent (SNP) | VAF 12/37 reads (32%) | catalogued as COSV52980686; called by muse, mutect2, varscan2
- CUX2 | c.1713C>A p.I571= | Silent (SNP) | VAF 31/92 reads (34%) | catalogued as COSV55644195, COSV99918947; called by muse, mutect2, varscan2
- EVPL | c.5697C>A p.A1899= | Silent (SNP) | VAF 16/129 reads (12%) | catalogued as COSV56914725; called by muse, mutect2, varscan2
- FRG2 | c.441A>G p.G147= | Silent (SNP) | VAF 24/140 reads (17%) | called by muse, mutect2, varscan2
- G6PD | c.1179C>T p.R393= | Silent (SNP) | VAF 25/94 reads (27%) | catalogued as rs782459284, COSV63703631; called by muse, mutect2
- GANAB | c.927C>T p.R309= | Silent (SNP) | VAF 50/192 reads (26%) | catalogued as rs766357143, COSV60467874; called by muse, mutect2, varscan2
- KLRF1 | c.561G>A p.V187= | Silent (SNP) | VAF 12/83 reads (14%) | catalogued as COSV54381638; called by muse, mutect2, varscan2
- LPA | c.2652T>C p.P884= | Silent (SNP) | VAF 92/227 reads (41%) | catalogued as COSV60299443; called by muse, mutect2, varscan2
- MEOX2 | c.906G>A p.A302= | Silent (SNP) | VAF 10/83 reads (12%) | catalogued as rs777058351, COSV56287124; called by muse, mutect2
- OPN1LW | c.315C>T p.I105= | Silent (SNP) | VAF 26/125 reads (21%) | catalogued as rs781829645, COSV64065148; called by muse, mutect2, varscan2
- OR2M5 | c.687A>T p.G229= | Silent (SNP) | VAF 56/395 reads (14%) | catalogued as COSV63546870; called by muse, mutect2, varscan2
- OR6M1 | c.786C>T p.N262= | Silent (SNP) | VAF 11/46 reads (24%) | catalogued as COSV58434520; called by muse, mutect2, varscan2
- PLAU | c.987G>A p.P329= | Silent (SNP) | VAF 24/120 reads (20%) | catalogued as rs754537952, COSV65641958; called by muse, mutect2, varscan2
- SCAF1 | c.3054A>C p.R1018= | Silent (SNP) | VAF 195/202 reads (97%) | catalogued as COSV62183507; called by muse, mutect2, varscan2
- TENM1 | c.5580T>C p.N1860= | Silent (SNP) | VAF 23/78 reads (29%) | catalogued as COSV64435936, COSV64440252; called by muse, mutect2, varscan2
- ACP4 | chr19:50798279 G>A | 3'Flank (SNP) | VAF 28/172 reads (16%) | catalogued as COSV54518411; called by muse, varscan2
- ACP4 | chr19:50798345 G>A | 3'Flank (SNP) | VAF 28/164 reads (17%) | catalogued as COSV54518414; called by muse, varscan2
- DNAH8 | c.-230C>T | 5'UTR (SNP) | VAF 27/55 reads (49%) | catalogued as COSV59454695; called by muse, mutect2, varscan2
- KRTAP10-3 | c.*1C>T | 3'UTR (SNP) | VAF 7/31 reads (23%) | catalogued as rs782543623, COSV59964233; called by muse, mutect2, varscan2
- ZNF467 | chr7:149777778 G>A | 5'Flank (SNP) | VAF 6/18 reads (33%) | catalogued as rs886089868, COSV50488948; called by muse, mutect2, varscan2
